Somatic mutation profile of tumor specimen ALCH-B003-TTP1-A (aliquot ALCH-B003-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-B003, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.1 years (20,130 days).
Specimen ALCH-B003-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41415f6c-82e1-4a8b-9652-515ef61ab231.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B003-NB1-A (Blood Derived Normal), aliquot ALCH-B003-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e00f77e-83fc-45f9-8b64-8a72f7758c70

The open-access MAF lists 58 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Nonsense Mutation 4, Intron 4, 3'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.6224G>A p.R2075K | Missense Mutation (SNP) | VAF 21/456 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV54127527; called by muse, mutect2
- CRAMP1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1157656622; called by muse, mutect2
- IGHV4-59 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 32/1160 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs375853107; called by muse, mutect2
- KCNC2 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 26/745 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54368827; called by muse, mutect2
- LHX8 | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 20/603 reads (3%) | catalogued as COSV53957785; called by muse, mutect2
- MAGEB18 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV100305657, COSV57465207; called by muse, mutect2
- MTTP | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 19/578 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV55505726; called by muse, mutect2
- MYH8 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 36/856 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1292287529; called by muse, mutect2
- NACA2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 42/1051 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1388775574, COSV71713114, COSV71713117; called by muse, mutect2
- NCOR2 | c.5722G>T p.A1908S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.082); catalogued as COSV62299553; called by muse, mutect2
- OR10AG1 | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV56631571; called by muse, mutect2
- OR2M3 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV71758897; called by muse, mutect2
- PCDH15 | c.2818G>T p.V940F | Missense Mutation (SNP) | VAF 31/871 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs1001539534; called by muse, mutect2
- PIK3R1 | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 24/742 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs962529901; called by muse, mutect2
- RRAGC | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 38/740 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65931667; called by muse, mutect2
- RYR2 | c.7199G>C p.G2400A | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as CM133737, COSV63691216; called by muse, mutect2
- SNAP25 | c.42G>T p.M14I | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1327509628, COSV54771367; called by muse, mutect2
- SYT14 | c.87G>T p.L29F | Missense Mutation (SNP) | VAF 56/664 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs945590528; called by muse, mutect2
- AOX1 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.026); called by muse, mutect2
- BPIFA1 | c.538T>A p.C180S | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CSMD1 | c.9682C>A p.Q3228K (on ENST00000520002; = p.Q3227K on NM_033225.6) | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); called by muse, mutect2
- IBA57 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NID2 | c.2919G>T p.Q973H | Missense Mutation (SNP) | VAF 8/211 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR5I1 | c.333T>A p.D111E | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- OTOGL | c.5354C>A p.A1785D (on ENST00000547103; = p.A1776D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- PARP8 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.891); called by muse, mutect2
- PCDH15 | c.5033C>A p.S1678* | Nonsense Mutation (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- PJA1 | c.293G>C p.R98T (on ENST00000361478 / NM_145119.4; = p.S98T on NM_022368.5) | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- PKD1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- POLD2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.12); called by muse, mutect2
- PORCN | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.04); called by muse, mutect2
- PTCHD4 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.751); called by muse, mutect2
- SLC8A1 | c.2409T>A p.C803* | Nonsense Mutation (SNP) | VAF 23/583 reads (4%) | called by muse, mutect2
- SPTA1 | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 72/816 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.543); called by muse, mutect2
- SPTBN1 | c.3274A>G p.N1092D | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2
- TACR3 | c.801C>A p.Y267* | Nonsense Mutation (SNP) | VAF 28/667 reads (4%) | called by muse, mutect2
- TLL1 | c.2470C>G p.H824D | Missense Mutation (SNP) | VAF 24/640 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZDHHC15 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF19 | c.561C>T p.S187= | Silent (SNP) | VAF 23/406 reads (6%) | called by muse, mutect2
- C3orf33 | c.603A>G p.L201= (on ENST00000340171 / NM_001308229.2; = p.L158= on NM_173657.2) | Silent (SNP) | VAF 10/301 reads (3%) | called by muse, mutect2
- FSCN2 | c.417G>T p.P139= | Silent (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- MEGF8 | c.6327G>T p.R2109= (on ENST00000251268 / NM_001271938.2; = p.R2042= on NM_001410.3) | Silent (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- MMGT1 | c.253A>C p.R85= | Silent (SNP) | VAF 12/255 reads (5%) | called by muse, mutect2
- OPN5 | c.96G>A p.A32= | Silent (SNP) | VAF 28/369 reads (8%) | catalogued as rs375496580, COSV55247204; called by muse, mutect2
- OR5M11 | c.258A>G p.V86= | Silent (SNP) | VAF 26/491 reads (5%) | called by muse, mutect2
- OR5P2 | c.663C>A p.I221= | Silent (SNP) | VAF 14/342 reads (4%) | catalogued as COSV61491462; called by muse, mutect2
- PAPPA2 | c.4407G>T p.P1469= | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- PCDHB5 | c.1317G>A p.L439= | Silent (SNP) | VAF 30/816 reads (4%) | catalogued as rs782527675; called by muse, mutect2
- PSMB11 | c.204T>G p.R68= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- RYR2 | c.5142T>C p.Y1714= | Silent (SNP) | VAF 25/378 reads (7%) | called by muse, mutect2
- SLITRK1 | c.1245G>A p.E415= | Silent (SNP) | VAF 33/1058 reads (3%) | called by muse, mutect2
- CACNB2 | c.213+110340T>A | Intron (SNP) | VAF 24/614 reads (4%) | called by muse, mutect2
- DIO3OS | chr14:101552603 C>T | 3'Flank (SNP) | VAF 17/356 reads (5%) | catalogued as rs1402330901; called by muse, mutect2
- FMO9P | n.363A>G | RNA (SNP) | VAF 15/323 reads (5%) | catalogued as rs1262999954; called by muse, mutect2
- GLMP | c.799-116G>C | Intron (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
- IDH3B | c.666-42G>C | Intron (SNP) | VAF 30/772 reads (4%) | called by muse, mutect2
- PLAGL2 | chr20:32189921 C>A | 3'Flank (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- RPS24 | c.*20-36C>T | Intron (SNP) | VAF 26/490 reads (5%) | called by muse, mutect2
